Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A74L, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A74L-01A (Primary Tumor).

Pathology Report for

Date of Surgery

Diagnosis:

Right parietal brain tumor
Oligoastrocytoma, grade II

Microscopic Description:

Microscopic evaluation reveals a diffusely infiltrating glioma. The tumor is composed of a proliferation of cells with predominantly round nuclei and variably prominent nuclear halos. Perineuronal satellitosis is identified. The tumor cells demonstrate mild to moderate cytologic atypia. Mitotic figures are not identified. The tumor demonstrates occasional foci of microcystic change. Neither necrosis nor microvascular proliferation are seen. Overall the histologic features appear consistent with the previous diagnosis (bx) per TSS. of low grade oligoastrocytoma. A final diagnosis will be issued pending review of special stains.

PW TSS, prior needle biopsy
on BCR

ICD-O-3
Oligoastrocytoma, grade II
9382/3
Site Case
Brain, supratentorial NOS
C71.0
path
Brain, parietal lobe
C71.3
JW 8/27/13

H2AA Discrepancy		✓

Source: NCI Genomic Data Commons file 2a06c19a-357c-4b71-bad0-6d892e060329 (TCGA-HT-A74L.FFB289B9-552E-4232-B2F7-9E93D72A7DD0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).